Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16G, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16G-01A (Primary Tumor).

[page 1 of 3]
1cb-0-3

Carcinoma, Serous, Nos

8441/3 12/9/10
/w

Surgical Pathology Site Code: Endometrium C54.1

TISSUE DESCRIPTION:

A1 A2 J1 J2 K1 K2 L1 M1 N1 B1 B2 B3 B4 B5 B6 B7
B8 B9 B10
B11 B12 B13 B14 B15 C1 C2 C3 C4 C5 C6 C7 C8 C9 C10 C11 C12
D1 D2 D3
D4 D5 D6 D7 D8 D9 D10 D11 E1 E2 E3 E4 F1 G1 G2 H1 H2 H3 H4
I1 I2 I3

Uterus, right ovary (3.1 x 1.5 x 1.1 cm) with 9.0 cm
segment of
right fallopian tube, and left ovary (2.8 x 1.7 x 1.1 cm)
with 9.0
cm segment of left fallopian tube together weighing 125.0
grams,
tissue from the bladder peritoneum (4.1 x 1.6 x 0.2 cm),
left colic
gutter (aggregating 2.3 x 1.9 x 0.5 cm), right colic
gutter
(aggregating 3.9 x 2.4 x 0.3 cm), tissue from the
diaphragm (2
pieces aggregating 0.5 x 0.4 x 0.4 cm), small bowel
mesentery
(biopsy, 0.4 x 0.3 x 0.2 cm), portion of omentum
(aggregating 15.0 x
6.5 x 2.8 cm), appendix (8.3 x 0.4 cm), right and left
pelvic lymph
nodes, right and left para-aortic lymph nodes.

DIAGNOSIS:

Uterus, total abdominal hysterectomy: High grade serous carcinoma
forming a mass (4.8 x 4.7 x 3.6 cm) arising in association
with an
endometrial polyp. The tumor invades throughout the
thickness of
the myometrium to focally involve the uterine serosa.
Lymphovascular invasion is present. The cervix is
unremarkable.

Ovary, left, oophorectomy: Endometrioma with focal
hyperplasia (1.1
cm).

Ovary, right, oophorectomy: No diagnostic abnormalities.

[page 2 of 3]
Fallopian tubes, right and left, salpingectomies: No
diagnostic
abnormalities.

Soft tissue, bladder peritoneum, excision: Involved by
high grade
serous carcinoma.

Peritoneum, right and left colic gutter, biopsies:
Negative for
tumor. Frozen section histologic interpretation performed
by:

Peritoneum, diaphragm, biopsy: Negative for tumor. Frozen
section
histologic interpretation performed by:

Mesentery, small bowel, biopsy: Negative for tumor.
Frozen section
histologic interpretation performed by:

Omentum, omentectomy: Involved by high grade serous
carcinoma.
Frozen section histologic interpretation performed by:

M.D.

Appendix, appendectomy: Fibrous obliteration of appendix.
Frozen
section histologic interpretation performed by:

Lymph nodes, right pelvic, excision: Multiple right
pelvic lymph
nodes (1 internal iliac, 8 external iliac, 2 common iliac
and 6
obturator) are negative for tumor. Frozen section
histologic
interpretation performed by:

Lymph nodes, left pelvic, excision: Multiple left pelvic
lymph
nodes (3 external iliac, 6 common iliac and 4 obturator)
are
negative for tumor. Frozen section histologic
interpretation
performed by:

[page 3 of 3]
Lymph nodes, right para-aortic, excision: Multiple right para-aortic lymph nodes (4 above and 7 below the inferior mesenteric artery) are negative for tumor. Frozen section histologic interpretation performed by:

Lymph nodes, left para-aortic, excision: Multiple left para-aortic lymph nodes (4 above the inferior mesenteric artery) are negative for tumor. Specimen labeled as "left para-aortic lymph nodes below the inferior mesenteric artery" revealed no nodal tissue.

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s).

Source: NCI Genomic Data Commons file bf28b3c8-9e33-4b35-bae8-1d78830fdfb3 (TCGA-D1-A16G.778F9F58-841E-48F3-B6EA-7CF58463808B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).